Somatic mutation profile of tumor specimen ALCH-ACFN-TTP1-A (aliquot ALCH-ACFN-TTP1-A-2-0-D-A501-36) from ALCHEMIST case ALCH-ACFN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.0 years (24,097 days).
Specimen ALCH-ACFN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7312d320-2c6f-42de-b8f8-f477fe90df53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ACFN-NB1-A (Blood Derived Normal), aliquot ALCH-ACFN-NB1-A-1-0-D-A501-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44a303a2-3ac7-41e0-a939-40db04e8c773

The open-access MAF lists 101 somatic variants for this specimen: 75 protein-altering or splice-affecting, 16 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 16, Nonsense Mutation 5, Intron 4, RNA 3, 3'UTR 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 26/518 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 96/392 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 27/170 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.51); PolyPhen benign (0.366); catalogued as COSV55875690, COSV55899999; called by muse, mutect2, varscan2
- BTN2A1 | c.1314T>G p.D438E | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs750329066; called by muse, mutect2
- CFAP44 | c.3071G>A p.R1024Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as rs539317195, COSV101204014; called by mutect2, varscan2
- COL4A4 | c.4840C>A p.Q1614K | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553612039; called by muse, mutect2
- COX7A2L | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs185444762, COSV52243747; called by muse, mutect2, varscan2
- DROSHA | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 20/199 reads (10%) | catalogued as rs373494822; called by muse, mutect2, varscan2
- EFEMP1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 25/346 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753826959, COSV62614817; called by muse, mutect2
- GPR149 | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 26/566 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.205); catalogued as COSV67671107; called by muse, mutect2
- GRIN2A | c.2128C>T p.Q710* | Nonsense Mutation (SNP) | VAF 64/523 reads (12%) | catalogued as rs1555491637, COSV100410940; called by muse, mutect2, varscan2
- GRIN3A | c.1865G>C p.R622T | Missense Mutation (SNP) | VAF 46/476 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV62458827; called by muse, mutect2, varscan2
- GSG1L | c.892C>A p.P298T (on ENST00000447459 / NM_001109763.2; = p.P143T on NM_144675.2) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.206); catalogued as rs1366316712; called by muse, mutect2, varscan2
- H3-4 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as COSV64210419; called by muse, mutect2
- HNRNPR | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.528); catalogued as rs1374998251, COSV100164429; called by muse, mutect2
- ITGA4 | c.1091A>G p.Y364C | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1170300224, COSV52000210; called by muse, mutect2, varscan2
- KIF20B | c.3127C>G p.R1043G (on ENST00000371728 / NM_001284259.2; = p.R1003G on NM_016195.4) | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53310006, COSV53315786; called by muse, mutect2, varscan2
- KMT2B | c.3206C>A p.S1069Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV55857669, COSV55866786; called by muse, mutect2, varscan2
- KNL1 | c.2202C>G p.F734L (on ENST00000346991 / NM_170589.5; = p.F708L on NM_144508.5) | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs372710483; called by muse, mutect2
- LDLRAD4 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.73); catalogued as COSV63333482; called by muse, varscan2
- NEK8 | c.1220C>G p.T407S | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as rs749473321; called by muse, mutect2, varscan2
- NEMP2 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100557398; called by muse, mutect2
- OR7E24 | c.892G>C p.V298L | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs1275136386; called by muse, mutect2, varscan2
- PCDHB8 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 40/542 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1184271669, COSV50753818; called by muse, mutect2
- PHYH | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 11/299 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1298954728, COSV53814980; called by muse, mutect2
- PSG5 | c.700A>T p.N234Y | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1371325349; called by muse, mutect2
- PUM1 | c.2701G>A p.V901I | Missense Mutation (SNP) | VAF 21/354 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as rs1184358006, COSV57081195; called by muse, mutect2
- RASAL1 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs762631941; called by mutect2, varscan2
- SCART1 | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs571055939; called by muse, mutect2, varscan2
- SMC3 | c.1985G>A p.G662D | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62419573, COSV62420076; called by muse, mutect2, varscan2
- SOS1 | c.2814G>C p.L938F | Missense Mutation (SNP) | VAF 39/342 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV67676504; called by muse, mutect2, varscan2
- SPTAN1 | c.4347G>C p.L1449= | Splice Region (SNP) | VAF 12/318 reads (4%) | catalogued as COSV63986908; called by muse, mutect2
- SUPT6H | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as rs1288969489; called by muse, mutect2
- SV2C | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59220754; called by muse, mutect2, varscan2
- TTN | c.81988G>A p.G27330R (on ENST00000591111; = p.G19906R on NM_003319.4) | Missense Mutation (SNP) | VAF 26/225 reads (12%) | PolyPhen probably damaging (1); catalogued as rs368921501; called by muse, mutect2, varscan2
- ZBTB4 | c.1840G>A p.V614I | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs759597062; called by muse, mutect2
- ZFHX4 | c.5227A>G p.I1743V | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.608); catalogued as COSV51475202; called by muse, mutect2
- ZSWIM8 | c.5408T>C p.M1803T (on ENST00000605216 / NM_001242487.2; = p.M1808T on NM_015037.3) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.04); catalogued as rs375107000; called by muse, mutect2, varscan2
- ACTN2 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AMY2B | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 26/814 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2
- ASB16 | c.1300C>G p.L434V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- B3GNT5 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCDC150 | c.1612G>C p.D538H | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CHD7 | c.2248T>C p.S750P | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CREB3L3 | c.628T>G p.C210G | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTAGE4 | c.2146A>G p.R716G | Missense Mutation (SNP) | VAF 54/1589 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- DMAP1 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2
- DNAH8 | c.3344A>G p.D1115G | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- H3C4 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); called by mutect2, varscan2
- KIF20B | c.2990C>A p.S997* (on ENST00000371728 / NM_001284259.2; = p.S957* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 37/263 reads (14%) | called by muse, mutect2, varscan2
- KRTAP19-8 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LTA4H | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 18/511 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2
- MAFA | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MAGEA12 | c.920G>T p.W307L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MAGEB16 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MTREX | c.1787G>C p.R596T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- OR10J3 | c.399T>G p.Y133* | Nonsense Mutation (SNP) | VAF 17/192 reads (9%) | called by muse, mutect2
- OR1J1 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PRRT4 | c.1159dup p.L387Pfs*192 | Frame Shift Ins (INS) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- PTK2 | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- RERE | c.844A>G p.T282A | Missense Mutation (SNP) | VAF 46/377 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- RYR2 | c.3374A>G p.D1125G | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2
- SLC44A1 | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SMC4 | c.1375A>C p.K459Q | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- SPATA7 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- SPRED1 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 32/618 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2
- TDRD7 | c.2781_2782del p.V928Hfs*9 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- TMEM202 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2
- TNFRSF6B | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM33 | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM3 | c.223G>T p.E75* (on ENST00000357533 / NM_001366142.2; = p.E44* on NM_001007471.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- TRRAP | c.2221A>G p.N741D | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2
- UMODL1 | c.3614T>A p.F1205Y (on ENST00000408910 / NM_001004416.2; = p.F1333Y on NM_173568.3) | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF280A | c.1546C>A p.Q516K | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZNF574 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1749A>G p.E583= | Silent (SNP) | VAF 47/370 reads (13%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.846C>G p.L282= | Silent (SNP) | VAF 34/362 reads (9%) | catalogued as COSV51951247; called by muse, mutect2
- CNOT6 | c.1635G>A p.L545= | Silent (SNP) | VAF 38/198 reads (19%) | called by muse, mutect2, varscan2
- GABRA4 | c.684G>A p.G228= | Silent (SNP) | VAF 15/206 reads (7%) | called by muse, mutect2
- GNG3 | c.174G>A p.V58= | Silent (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- HDGFL3 | c.219A>G p.G73= | Silent (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- KDM6B | c.3012G>A p.K1004= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1232193315; called by muse, mutect2, varscan2
- KMT2D | c.10809G>A p.Q3603= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1555189181, COSV56409836; called by mutect2, varscan2
- NBEAL1 | c.3405A>G p.G1135= | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- OR6C1 | c.210G>A p.S70= | Silent (SNP) | VAF 25/170 reads (15%) | catalogued as rs375702387; called by muse, mutect2, varscan2
- PTGS1 | c.1698G>T p.L566= | Silent (SNP) | VAF 27/194 reads (14%) | called by muse, mutect2, varscan2
- RABEP2 | c.1101C>G p.V367= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- RABGAP1L | c.495C>G p.P165= | Silent (SNP) | VAF 13/318 reads (4%) | catalogued as rs894232018, COSV52315720; called by muse, mutect2
- SLC2A3 | c.249C>G p.L83= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as COSV50002686; called by muse, mutect2, varscan2
- SLC30A10 | c.1389G>C p.L463= | Silent (SNP) | VAF 23/170 reads (14%) | called by muse, varscan2
- VPS36 | c.666G>C p.L222= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- AC024940.1 | n.3672C>G | RNA (SNP) | VAF 24/214 reads (11%) | catalogued as rs374325982; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847962 C>T | 5'Flank (SNP) | VAF 30/349 reads (9%) | called by muse, mutect2
- DCDC1 | c.5074-2154C>G | Intron (SNP) | VAF 5/73 reads (7%) | catalogued as rs1327206279; called by muse, mutect2
- FAM172BP | n.256G>A | RNA (SNP) | VAF 18/336 reads (5%) | called by muse, mutect2
- NDUFS2 | c.1297-38A>G | Intron (SNP) | VAF 54/319 reads (17%) | catalogued as rs758904393; called by muse, mutect2, varscan2
- PFDN1 | c.*490C>T | 3'UTR (SNP) | VAF 9/188 reads (5%) | called by muse, mutect2
- RELN | c.*24del | 3'UTR (DEL) | VAF 31/272 reads (11%) | catalogued as rs746857941; called by mutect2, varscan2
- SFTPC | c.435+22G>C | Intron (SNP) | VAF 32/192 reads (17%) | called by muse, mutect2, varscan2
- SPPL2B | c.956+593T>A | Intron (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- ZNF833P | n.760G>A | RNA (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
